Somatic mutation profile of tumor specimen TCGA-ER-A19A-06A (aliquot TCGA-ER-A19A-06A-21D-A197-08) from TCGA case TCGA-ER-A19A, project TCGA-SKCM (Skin Cutaneous Melanoma). Sex at birth: male; Vital status: Alive; Primary diagnosis: Malignant melanoma, NOS; Tissue or organ of origin: Skin, NOS; Age at diagnosis: 80.0 years (29,208 days).
Specimen TCGA-ER-A19A-06A: Sample type: Metastatic; Tissue type: Tumor; Tumor descriptor: Metastatic; Preservation method: OCT.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) 13f136e9-d6c3-4e89-93a4-1fae0d9d9853.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen TCGA-ER-A19A-10A (Blood Derived Normal), aliquot TCGA-ER-A19A-10A-01D-A199-08; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/9e8fdef4-0e0f-4a1f-b4bb-a86ff9008fd3

The open-access MAF lists 183 somatic variants for this specimen: 119 protein-altering or splice-affecting, 61 silent, 3 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 114, Silent 61, Nonsense Mutation 4, Intron 3, Splice Region 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- ABL2 | c.2374C>T p.P792S (on ENST00000502732 / NM_007314.4; = p.P777S on NM_005158.5) | Missense Mutation (SNP) | VAF 17/137 reads (12%) | SIFT deleterious, low confidence (0.01); PolyPhen benign (0.41); catalogued as COSV61014524; called by muse, mutect2, varscan2
- ACTRT1 | c.1079C>T p.S360L | Missense Mutation (SNP) | VAF 12/118 reads (10%) | SIFT deleterious (0.05); PolyPhen benign (0.121); catalogued as rs376262844, COSV64419456, COSV64420221; called by muse, mutect2
- ADAM12 | c.1304G>A p.G435E | Missense Mutation (SNP) | VAF 12/164 reads (7%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV64107034; called by muse, mutect2
- ADGRL2 | c.3155C>T p.S1052F (on ENST00000370717 / NM_001366005.1; = p.S1039F on NM_012302.4) | Missense Mutation (SNP) | VAF 10/214 reads (5%) | SIFT deleterious (0); PolyPhen probably damaging (0.956); catalogued as COSV54668003; called by muse, mutect2
- ADGRV1 | c.608G>A p.G203E | Missense Mutation (SNP) | VAF 5/25 reads (20%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV67985626; called by muse, mutect2, varscan2
- AL592490.1 | c.1205G>A p.G402E | Missense Mutation (SNP) | VAF 7/115 reads (6%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.996); catalogued as COSV69426353; called by muse, mutect2
- ANK3 | c.13019G>A p.R4340K (on ENST00000280772 / NM_001320874.2; = p.R964K on NM_001149.3) | Missense Mutation (SNP) | VAF 12/263 reads (5%) | SIFT deleterious, low confidence (0.03); PolyPhen possibly damaging (0.566); catalogued as COSV55058713; called by muse, mutect2
- ANKS1A | c.2627C>T p.P876L | Missense Mutation (SNP) | VAF 9/59 reads (15%) | SIFT tolerated (0.07); PolyPhen probably damaging (0.998); catalogued as COSV64460867; called by muse, mutect2, varscan2
- APOBEC3G | c.794T>G p.V265G | Missense Mutation (SNP) | VAF 6/98 reads (6%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.737); catalogued as COSV68470324; called by muse, mutect2
- ATP11C | c.3164G>A p.R1055K | Missense Mutation (SNP) | VAF 10/44 reads (23%) | SIFT tolerated (0.1); PolyPhen probably damaging (0.992); catalogued as COSV59564316; called by muse, mutect2, varscan2
- BEND2 | c.595G>A p.E199K | Missense Mutation (SNP) | VAF 15/114 reads (13%) | SIFT deleterious (0.02); PolyPhen benign (0.118); catalogued as COSV66215859; called by muse, mutect2, varscan2
- C2 | c.2032G>A p.E678K | Missense Mutation (SNP) | VAF 20/599 reads (3%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.992); catalogued as rs756513158, COSV100190551, COSV100191548; called by muse, mutect2
- C6orf201 | c.259C>T p.P87S | Missense Mutation (SNP) | VAF 6/38 reads (16%) | SIFT deleterious (0.02); PolyPhen benign (0.324); catalogued as COSV60986659; called by muse, mutect2
- CARD11 | c.166G>A p.D56N | Missense Mutation (SNP) | VAF 6/129 reads (5%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV62717671; called by muse, mutect2
- CARS1 | c.977C>T p.S326F | Missense Mutation (SNP) | VAF 7/96 reads (7%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs866985601, COSV53454684; called by muse, mutect2
- CEACAM6 | c.502G>A p.E168K | Missense Mutation (SNP) | VAF 12/211 reads (6%) | SIFT deleterious (0.01); PolyPhen benign (0.251); catalogued as COSV52267617; called by muse, mutect2
- CELA2A | c.236G>A p.R79K | Missense Mutation (SNP) | VAF 6/112 reads (5%) | SIFT tolerated (0.21); PolyPhen benign (0.001); catalogued as COSV100657633, COSV62747368; called by muse, mutect2
- CHD4 | c.1448C>T p.P483L (on ENST00000357008 / NM_001363606.2; = p.P496L on NM_001273.5) | Missense Mutation (SNP) | VAF 9/134 reads (7%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.998); catalogued as COSV58901520; called by muse, mutect2
- CNBD2 | c.225G>A p.M75I | Missense Mutation (SNP) | VAF 7/113 reads (6%) | SIFT tolerated (0.34); PolyPhen benign (0.023); catalogued as COSV62587040; called by muse, mutect2
- COL14A1 | c.5239C>T p.P1747S | Missense Mutation (SNP) | VAF 7/88 reads (8%) | SIFT tolerated (0.19); PolyPhen probably damaging (0.996); catalogued as COSV52853371; called by muse, mutect2
- CPB1 | c.910C>T p.H304Y | Missense Mutation (SNP) | VAF 7/88 reads (8%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV51573635; called by muse, mutect2
- CPOX | c.1031C>T p.S344F | Missense Mutation (SNP) | VAF 8/143 reads (6%) | SIFT deleterious (0.01); PolyPhen benign (0.127); catalogued as rs1374535430, COSV51638424; called by muse, mutect2
- CSNK1E | c.376C>T p.H126Y | Missense Mutation (SNP) | VAF 8/89 reads (9%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (1); catalogued as COSV63291044; called by muse, mutect2
- CUL3 | c.1066C>T p.L356F | Missense Mutation (SNP) | VAF 4/42 reads (10%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.993); catalogued as rs1206525768, COSV52364995; called by muse, mutect2
- CYP4F12 | c.506A>G p.K169R | Missense Mutation (SNP) | VAF 5/68 reads (7%) | SIFT tolerated (0.12); PolyPhen benign (0.015); catalogued as rs1422029350, COSV61173876; called by muse, mutect2
- DCLK3 | c.559C>T p.P187S | Missense Mutation (SNP) | VAF 5/93 reads (5%) | SIFT tolerated (0.72); PolyPhen benign (0.011); catalogued as COSV69363204; called by muse, mutect2
- DIDO1 | c.3857C>T p.P1286L | Missense Mutation (SNP) | VAF 11/131 reads (8%) | SIFT tolerated (0.34); PolyPhen benign (0); catalogued as COSV56622832; called by muse, mutect2
- DMC1 | c.838T>A p.F280I | Missense Mutation (SNP) | VAF 8/98 reads (8%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.951); catalogued as COSV99319109; called by muse, mutect2
- DMC1 | c.837C>T p.T279= | Splice Region (SNP) | VAF 8/98 reads (8%) | catalogued as COSV99319112; called by muse, mutect2
- DSE | c.568G>A p.E190K | Missense Mutation (SNP) | VAF 5/45 reads (11%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.99); catalogued as COSV59064111; called by muse, mutect2
- EEF2K | c.1111C>T p.P371S | Missense Mutation (SNP) | VAF 6/91 reads (7%) | SIFT tolerated (0.09); PolyPhen benign (0.17); catalogued as rs1263817446, COSV53782199; called by muse, mutect2
- EGFL6 | c.641G>A p.R214Q | Missense Mutation (SNP) | VAF 6/66 reads (9%) | SIFT tolerated (0.08); PolyPhen benign (0.334); catalogued as rs780194370, COSV63633283; called by mutect2, varscan2
- ESYT3 | c.1277C>T p.S426L | Missense Mutation (SNP) | VAF 32/681 reads (5%) | SIFT deleterious (0); PolyPhen benign (0.172); catalogued as COSV67440932; called by muse, mutect2
- FAM47C | c.1202C>T p.P401L | Missense Mutation (SNP) | VAF 6/43 reads (14%) | SIFT tolerated (0.67); PolyPhen benign (0); catalogued as rs542100893, COSV63726730; called by muse, mutect2
- FN1 | c.2683C>T p.Q895* | Nonsense Mutation (SNP) | VAF 8/118 reads (7%) | catalogued as COSV60547828; called by muse, mutect2
- FYB2 | c.1261C>T p.Q421* | Nonsense Mutation (SNP) | VAF 8/58 reads (14%) | catalogued as rs867450471, COSV58582957; called by muse, mutect2, varscan2
- GALNT16 | c.565G>A p.E189K | Missense Mutation (SNP) | VAF 7/73 reads (10%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); catalogued as COSV61886075; called by muse, mutect2
- GALR3 | c.776G>A p.W259* | Nonsense Mutation (SNP) | VAF 4/26 reads (15%) | catalogued as COSV50764019; called by muse, mutect2
- GLRB | c.706G>A p.E236K | Missense Mutation (SNP) | VAF 7/82 reads (9%) | SIFT deleterious (0.02); PolyPhen benign (0.433); catalogued as COSV52412919; called by muse, mutect2
- GNAT2 | c.826G>A p.E276K | Missense Mutation (SNP) | VAF 6/62 reads (10%) | SIFT tolerated (0.07); PolyPhen benign (0.013); catalogued as COSV63554745; called by muse, mutect2, varscan2
- GPR34 | c.590G>A p.G197E | Missense Mutation (SNP) | VAF 3/23 reads (13%) | SIFT tolerated (1); PolyPhen benign (0.007); catalogued as COSV59367004; called by muse, mutect2
- HECW1 | c.592G>A p.G198R | Missense Mutation (SNP) | VAF 6/92 reads (7%) | SIFT tolerated (0.06); PolyPhen benign (0.408); catalogued as COSV67829964; called by muse, mutect2
- IZUMO1 | c.79C>T p.P27S | Missense Mutation (SNP) | VAF 10/138 reads (7%) | SIFT deleterious (0.05); PolyPhen benign (0.038); catalogued as COSV59568357; called by muse, mutect2
- KBTBD8 | c.1300C>T p.H434Y | Missense Mutation (SNP) | VAF 7/135 reads (5%) | SIFT tolerated (1); PolyPhen benign (0.201); catalogued as COSV55128626; called by muse, mutect2
- LPAR2 | c.31G>A p.E11K | Missense Mutation (SNP) | VAF 8/136 reads (6%) | SIFT tolerated (0.43); PolyPhen benign (0.029); catalogued as rs1344693204, COSV52556273; called by muse, mutect2
- LUZP4 | c.671G>A p.R224K | Missense Mutation (SNP) | VAF 7/70 reads (10%) | SIFT deleterious (0.02); PolyPhen benign (0.246); catalogued as COSV64218963; called by muse, mutect2
- MAGEA6 | c.724C>T p.P242S | Missense Mutation (SNP) | VAF 11/131 reads (8%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.816); catalogued as rs782385960, COSV61449015; called by muse, mutect2
- MAP3K15 | c.3215C>T p.S1072L | Missense Mutation (SNP) | VAF 6/56 reads (11%) | SIFT tolerated (0.32); PolyPhen probably damaging (0.996); catalogued as COSV58830458, COSV58833295; called by muse, mutect2
- MDN1 | c.14347G>A p.D4783N | Missense Mutation (SNP) | VAF 6/154 reads (4%) | SIFT tolerated (0.09); PolyPhen benign (0.006); catalogued as COSV65521891; called by muse, mutect2
- MEGF11 | c.820G>A p.D274N | Missense Mutation (SNP) | VAF 3/35 reads (9%) | SIFT deleterious (0.04); PolyPhen benign (0.02); catalogued as COSV56551118; called by muse, mutect2
- MFSD6 | c.1085C>T p.P362L | Missense Mutation (SNP) | VAF 4/38 reads (11%) | SIFT tolerated (0.47); PolyPhen benign (0); catalogued as COSV55622754; called by muse, mutect2
- MMD2 | c.128C>T p.A43V | Missense Mutation (SNP) | VAF 7/137 reads (5%) | SIFT deleterious (0); PolyPhen probably damaging (0.924); catalogued as COSV68660682; called by muse, mutect2
- MUC16 | c.4118C>T p.S1373L | Missense Mutation (SNP) | VAF 7/122 reads (6%) | SIFT deleterious, low confidence (0); PolyPhen benign (0); catalogued as COSV67441190; called by muse, mutect2
- MUC17 | c.6644C>T p.P2215L | Missense Mutation (SNP) | VAF 22/392 reads (6%) | SIFT tolerated (0.08); PolyPhen benign (0.009); catalogued as rs1176247433, COSV60289255; called by muse, mutect2
- MUC17 | c.7357G>A p.E2453K | Missense Mutation (SNP) | VAF 20/424 reads (5%) | SIFT deleterious (0.04); PolyPhen possibly damaging (0.636); catalogued as COSV60286359; called by muse, mutect2
- MUC17 | c.10495C>T p.P3499S | Missense Mutation (SNP) | VAF 13/264 reads (5%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.963); catalogued as COSV60289267; called by muse, mutect2
- NCKAP1L | c.3341G>A p.R1114Q | Missense Mutation (SNP) | VAF 11/149 reads (7%) | SIFT deleterious (0); PolyPhen probably damaging (0.992); catalogued as rs867197350, COSV53203951; called by muse, mutect2
- NF1 | c.8261C>T p.S2754F (on ENST00000358273 / NM_001042492.3; = p.S2733F on NM_000267.3) | Missense Mutation (SNP) | VAF 8/113 reads (7%) | SIFT deleterious, low confidence (0.01); PolyPhen possibly damaging (0.467); catalogued as COSV62193491; called by muse, mutect2
- NOTCH2 | c.7037C>T p.A2346V | Missense Mutation (SNP) | VAF 22/616 reads (4%) | SIFT tolerated (0.23); PolyPhen benign (0.14); catalogued as rs978683539, COSV56691947; called by muse, mutect2
- NUP210L | c.1786G>A p.D596N | Missense Mutation (SNP) | VAF 5/86 reads (6%) | SIFT tolerated (0.08); PolyPhen benign (0.227); catalogued as COSV55148133; called by muse, mutect2
- OR12D2 | c.25G>A p.E9K | Missense Mutation (SNP) | VAF 18/259 reads (7%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.796); catalogued as rs1458564754, COSV65826259; called by muse, mutect2
- OR51F2 | c.439G>A p.G147R | Missense Mutation (SNP) | VAF 13/202 reads (6%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.737); catalogued as COSV59064168, COSV59064825; called by muse, mutect2
- PAK3 | c.217C>T p.P73S | Missense Mutation (SNP) | VAF 7/134 reads (5%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV53273963; called by muse, mutect2
- PCDH11Y | c.373C>T p.R125C (on ENST00000400457 / NM_032973.2; = p.R114C on NM_032971.3) | Missense Mutation (SNP) | VAF 10/114 reads (9%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV53081190; called by muse, mutect2
- PCDH18 | c.2347C>T p.P783S | Missense Mutation (SNP) | VAF 6/52 reads (12%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.996); catalogued as COSV61268410, COSV61268565; called by muse, mutect2, varscan2
- PCDH18 | c.19A>C p.K7Q | Missense Mutation (SNP) | VAF 7/87 reads (8%) | SIFT tolerated, low confidence (0.05); PolyPhen benign (0.014); catalogued as COSV61268572; called by muse, mutect2
- PDE1A | c.915G>A p.M305I | Missense Mutation (SNP) | VAF 4/31 reads (13%) | SIFT tolerated (0.05); PolyPhen benign (0.005); catalogued as rs1158580384, COSV59514623; called by muse, mutect2
- PDYN | c.19G>A p.V7I | Missense Mutation (SNP) | VAF 6/62 reads (10%) | SIFT tolerated (0.18); PolyPhen benign (0.012); catalogued as COSV54101833; called by muse, mutect2
- PLCB4 | c.2963G>A p.G988E | Missense Mutation (SNP) | VAF 5/64 reads (8%) | SIFT tolerated (0.61); PolyPhen benign (0); catalogued as COSV53802446, COSV99595102; called by muse, mutect2
- PLG | c.2113G>A p.G705R | Missense Mutation (SNP) | VAF 6/62 reads (10%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV57516335; called by muse, mutect2
- PLPPR1 | c.140G>A p.G47E | Missense Mutation (SNP) | VAF 6/83 reads (7%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as rs867093135, COSV66453407; called by muse, mutect2
- POP1 | c.743C>T p.S248F | Missense Mutation (SNP) | VAF 7/108 reads (6%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV62892851; called by muse, mutect2
- PYGO1 | c.671C>T p.P224L | Missense Mutation (SNP) | VAF 5/100 reads (5%) | SIFT deleterious (0.03); PolyPhen benign (0); catalogued as rs1183146996, COSV57347856; called by muse, mutect2
- RASGRF1 | c.838C>T p.P280S | Missense Mutation (SNP) | VAF 14/180 reads (8%) | SIFT deleterious (0.05); PolyPhen benign (0.077); catalogued as rs758583458, COSV69179108; called by muse, mutect2
- REG4 | c.433G>A p.E145K | Missense Mutation (SNP) | VAF 32/515 reads (6%) | SIFT tolerated (0.41); PolyPhen benign (0.045); catalogued as rs150927973; called by muse, mutect2
- SAGE1 | c.2111G>A p.G704E | Missense Mutation (SNP) | VAF 7/68 reads (10%) | SIFT tolerated (0.1); PolyPhen possibly damaging (0.808); catalogued as COSV61013642; called by muse, mutect2, varscan2
- SCN1A | c.5380G>A p.E1794K (on ENST00000303395 / NM_001202435.3; = p.E1783K on NM_006920.6 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 8/117 reads (7%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV57670818; called by muse, mutect2
- SH3TC2 | c.496G>A p.E166K | Missense Mutation (SNP) | VAF 6/83 reads (7%) | SIFT tolerated (0.26); PolyPhen benign (0.297); catalogued as COSV60463498; called by muse, mutect2
- SHANK3 | c.3290C>T p.P1097L | Missense Mutation (SNP) | VAF 5/17 reads (29%) | SIFT deleterious (0); PolyPhen possibly damaging (0.785); catalogued as rs1362739152, COSV53186804; called by muse, mutect2
- SHROOM2 | c.3532C>T p.P1178S | Missense Mutation (SNP) | VAF 3/24 reads (13%) | SIFT deleterious (0); PolyPhen possibly damaging (0.829); catalogued as COSV66606857; called by muse, mutect2
- SLC10A3 | c.1010G>A p.G337D | Missense Mutation (SNP) | VAF 5/59 reads (8%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV99681970; called by muse, mutect2
- SLC30A8 | c.185A>T p.K62M | Missense Mutation (SNP) | VAF 22/528 reads (4%) | SIFT deleterious (0.05); PolyPhen benign (0.018); catalogued as COSV69970807; called by muse, mutect2
- SLC38A4 | c.701T>A p.V234E | Missense Mutation (SNP) | VAF 7/107 reads (7%) | SIFT deleterious (0); PolyPhen possibly damaging (0.882); catalogued as COSV56967617; called by muse, mutect2
- SMTNL2 | c.605G>A p.R202Q (on ENST00000389313 / NM_001114974.2; = p.R58Q on NM_198501.3) | Missense Mutation (SNP) | VAF 8/56 reads (14%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.567); catalogued as rs767203172, COSV58807015; called by mutect2, varscan2
- SPAG1 | c.1988G>A p.R663K | Missense Mutation (SNP) | VAF 6/93 reads (6%) | SIFT deleterious (0.05); PolyPhen probably damaging (0.958); catalogued as COSV52560032; called by muse, mutect2
- STK31 | c.1198G>A p.G400R | Missense Mutation (SNP) | VAF 7/95 reads (7%) | SIFT tolerated (0.07); PolyPhen possibly damaging (0.459); catalogued as rs1167542484, COSV63456153; called by muse, mutect2
- STK31 | c.1517G>A p.R506K | Missense Mutation (SNP) | VAF 6/100 reads (6%) | SIFT tolerated (0.96); PolyPhen benign (0.026); catalogued as rs1385214894, COSV63456157; called by muse, mutect2
- SULT2A1 | c.71G>A p.R24K | Missense Mutation (SNP) | VAF 9/121 reads (7%) | SIFT tolerated (0.41); PolyPhen benign (0.003); catalogued as rs1423173698, COSV55765009; called by muse, mutect2
- SV2B | c.1948G>A p.G650R | Missense Mutation (SNP) | VAF 44/763 reads (6%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); catalogued as COSV57699876; called by muse, mutect2
- SYT1 | c.538C>T p.P180S | Missense Mutation (SNP) | VAF 6/78 reads (8%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV54032324; called by muse, mutect2
- SYTL5 | c.49G>A p.E17K | Missense Mutation (SNP) | VAF 4/30 reads (13%) | SIFT deleterious (0); PolyPhen possibly damaging (0.858); catalogued as COSV52901323; called by muse, mutect2
- TAF1 | c.904T>C p.S302P (on ENST00000373790 / NM_138923.4; = p.S323P on NM_004606.5 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 4/36 reads (11%) | SIFT tolerated (0.18); PolyPhen benign (0.173); catalogued as COSV52113918; called by muse, mutect2
- THADA | c.4528C>T p.P1510S | Missense Mutation (SNP) | VAF 20/618 reads (3%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as COSV57683906; called by muse, mutect2
- THEMIS | c.838G>A p.E280K | Missense Mutation (SNP) | VAF 8/130 reads (6%) | SIFT tolerated (0.13); PolyPhen benign (0.115); catalogued as rs773188610, COSV64071269; called by muse, mutect2
- THSD4 | c.1486G>A p.E496K | Missense Mutation (SNP) | VAF 8/214 reads (4%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV55970632; called by muse, mutect2
- TIPRL | c.133C>G p.L45V | Missense Mutation (SNP) | VAF 4/95 reads (4%) | SIFT tolerated (0.08); PolyPhen benign (0.118); catalogued as COSV63207844; called by muse, mutect2
- TLL1 | c.389G>A p.G130E | Missense Mutation (SNP) | VAF 4/39 reads (10%) | SIFT tolerated (0.44); PolyPhen benign (0); catalogued as rs866987397, COSV50261937; called by muse, mutect2
- TNNI3K | c.1822G>A p.G608R | Missense Mutation (SNP) | VAF 9/122 reads (7%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); catalogued as COSV58554832; called by muse, mutect2
- TRAM1L1 | c.965G>A p.R322K | Missense Mutation (SNP) | VAF 8/170 reads (5%) | SIFT tolerated (0.25); PolyPhen benign (0.158); catalogued as rs1452181036, COSV60292028; called by muse, mutect2
- TRANK1 | c.2371G>A p.E791K | Missense Mutation (SNP) | VAF 12/287 reads (4%) | SIFT deleterious (0); PolyPhen possibly damaging (0.751); catalogued as COSV57142099; called by muse, mutect2
- TTC17 | c.3065C>T p.A1022V | Missense Mutation (SNP) | VAF 7/90 reads (8%) | SIFT deleterious (0); PolyPhen benign (0.197); catalogued as COSV50008731; called by muse, mutect2
- TULP2 | c.980G>A p.R327K | Missense Mutation (SNP) | VAF 7/69 reads (10%) | SIFT tolerated (0.98); PolyPhen benign (0.011); catalogued as COSV55478176; called by muse, mutect2, varscan2
- VN1R2 | c.733G>A p.D245N | Missense Mutation (SNP) | VAF 5/85 reads (6%) | SIFT deleterious (0.05); PolyPhen possibly damaging (0.759); catalogued as COSV59038377; called by muse, mutect2
- YWHAE | c.560C>T p.S187F | Missense Mutation (SNP) | VAF 8/86 reads (9%) | SIFT deleterious, low confidence (0); PolyPhen possibly damaging (0.647); catalogued as COSV51982596; called by muse, mutect2
- ZAN | c.787G>A p.D263N | Missense Mutation (SNP) | VAF 5/68 reads (7%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.99); catalogued as COSV61809400; called by muse, mutect2
- ZC3H13 | c.1568C>T p.P523L | Missense Mutation (SNP) | VAF 6/102 reads (6%) | SIFT tolerated, low confidence (0.11); PolyPhen benign (0); catalogued as rs1267724846, COSV54454252; called by muse, mutect2
- ZNF180 | c.1726C>T p.P576S | Missense Mutation (SNP) | VAF 6/80 reads (8%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV55421421; called by muse, mutect2
- ZNF287 | c.166C>T p.P56S | Missense Mutation (SNP) | VAF 6/84 reads (7%) | SIFT tolerated (0.73); PolyPhen benign (0.007); catalogued as COSV67688488; called by muse, mutect2
- ZNF543 | c.184G>T p.D62Y | Missense Mutation (SNP) | VAF 8/98 reads (8%) | SIFT deleterious (0); PolyPhen possibly damaging (0.556); catalogued as COSV58627560; called by muse, mutect2
- ZNF616 | c.1198C>T p.R400* | Nonsense Mutation (SNP) | VAF 9/132 reads (7%) | catalogued as rs1429459933, COSV57511162; called by muse, mutect2
- ZSWIM2 | c.479C>T p.P160L | Missense Mutation (SNP) | VAF 7/169 reads (4%) | SIFT deleterious (0); PolyPhen probably damaging (0.989); catalogued as COSV54575635; called by muse, mutect2
- ZXDA | c.2314T>G p.F772V | Missense Mutation (SNP) | VAF 6/45 reads (13%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.724); catalogued as COSV62388021; called by muse, mutect2, varscan2
- DST | c.385C>T p.H129Y | Missense Mutation (SNP) | VAF 13/243 reads (5%) | SIFT deleterious, low confidence (0); PolyPhen benign (0.063); called by muse, mutect2
- IGHE | c.275C>T p.S92L | Missense Mutation (SNP) | VAF 17/298 reads (6%) | SIFT deleterious (0); PolyPhen probably damaging (0.984); called by muse, mutect2
- IGHM | c.704T>G p.F235C | Missense Mutation (SNP) | VAF 10/225 reads (4%) | SIFT deleterious (0); PolyPhen possibly damaging (0.883); called by muse, mutect2
- PRAMEF20 | c.667G>A p.E223K | Missense Mutation (SNP) | VAF 20/510 reads (4%) | SIFT tolerated (1); PolyPhen benign (0.287); called by muse, mutect2
- SLC10A3 | c.1009G>A p.G337S | Missense Mutation (SNP) | VAF 5/59 reads (8%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2
- SUPT20HL2 | c.1813C>T p.P605S | Missense Mutation (SNP) | VAF 5/28 reads (18%) | SIFT tolerated (0.05); PolyPhen benign (0.258); called by muse, mutect2
- TRAV4 | c.91G>A p.E31K | Missense Mutation (SNP) | VAF 8/105 reads (8%) | SIFT deleterious (0); PolyPhen probably damaging (0.99); called by muse, mutect2
- ABCC8 | c.531C>T p.I177= | Silent (SNP) | VAF 17/505 reads (3%) | catalogued as rs1281825493, COSV56850837; called by muse, mutect2
- ACACA | c.2670C>T p.F890= | Silent (SNP) | VAF 6/84 reads (7%) | called by muse, mutect2
- ASMT | c.198C>T p.I66= | Silent (SNP) | VAF 5/51 reads (10%) | catalogued as COSV67109873; called by muse, mutect2
- ATG7 | c.1851C>T p.T617= | Silent (SNP) | VAF 7/152 reads (5%) | catalogued as COSV61612714; called by muse, mutect2
- ATP9A | c.255C>T p.F85= | Silent (SNP) | VAF 7/72 reads (10%) | catalogued as COSV58766806; called by muse, mutect2
- C1QTNF2 | c.141C>T p.I47= (on ENST00000393975; = p.I2= on NM_031908.6 and 1 other RefSeq transcript) | Silent (SNP) | VAF 4/30 reads (13%) | catalogued as COSV67432740; called by muse, mutect2
- CASP10 | c.1398G>A p.L466= (on ENST00000272879 / NM_032974.5; = p.L423= on NM_001230.5) | Silent (SNP) | VAF 8/128 reads (6%) | catalogued as COSV53778224; called by muse, mutect2
- CCR4 | c.618C>T p.I206= | Silent (SNP) | VAF 8/176 reads (5%) | catalogued as COSV58382364; called by muse, mutect2
- CDC20 | c.510C>T p.S170= | Silent (SNP) | VAF 12/266 reads (5%) | catalogued as COSV60522161; called by muse, mutect2
- CLIC2 | c.663C>T p.A221= | Silent (SNP) | VAF 8/52 reads (15%) | catalogued as COSV58936733; called by muse, mutect2, varscan2
- CREB5 | c.417G>A p.Q139= (on ENST00000357727 / NM_182898.4; = p.Q132= on NM_004904.3) | Silent (SNP) | VAF 24/517 reads (5%) | catalogued as COSV63221092; called by muse, mutect2
- DGKG | c.444C>T p.V148= | Silent (SNP) | VAF 20/390 reads (5%) | catalogued as rs1369294246, COSV53963145; called by muse, mutect2
- DICER1 | c.1440T>C p.T480= | Silent (SNP) | VAF 7/63 reads (11%) | catalogued as rs1555373201, COSV58620258; ClinVar: likely benign; called by muse, mutect2, varscan2
- EGFLAM | c.2049C>T p.V683= | Silent (SNP) | VAF 12/226 reads (5%) | catalogued as COSV59293903; called by muse, mutect2
- ENTPD2 | c.579G>A p.R193= | Silent (SNP) | VAF 7/71 reads (10%) | catalogued as COSV57074698; called by muse, mutect2
- FILIP1 | c.669C>T p.A223= | Silent (SNP) | VAF 5/51 reads (10%) | catalogued as COSV52730148; called by muse, mutect2, varscan2
- GABRQ | c.111C>T p.S37= | Silent (SNP) | VAF 6/44 reads (14%) | catalogued as COSV64782106; called by muse, mutect2
- GIMAP4 | c.729C>T p.L243= | Silent (SNP) | VAF 4/36 reads (11%) | catalogued as COSV55432500; called by muse, mutect2
- GIMAP5 | c.234C>T p.V78= | Silent (SNP) | VAF 6/78 reads (8%) | catalogued as COSV57530004; called by muse, mutect2
- GPR42 | c.114C>T p.V38= | Silent (SNP) | VAF 6/68 reads (9%) | catalogued as COSV71995017, COSV71995025; called by muse, mutect2, varscan2
- GRIN2B | c.3411C>T p.F1137= | Silent (SNP) | VAF 8/58 reads (14%) | catalogued as COSV74204629, COSV74204923; called by muse, mutect2
- HNF1A | c.546G>A p.Q182= | Silent (SNP) | VAF 18/427 reads (4%) | catalogued as COSV57462498; called by muse, mutect2
- HOXB5 | c.726C>T p.F242= | Silent (SNP) | VAF 9/169 reads (5%) | catalogued as COSV53313143; called by muse, mutect2
- HRNR | c.1902C>T p.S634= | Silent (SNP) | VAF 14/379 reads (4%) | catalogued as COSV64258170; called by muse, mutect2
- KCNH1 | c.2703G>A p.Q901= (on ENST00000271751 / NM_172362.3; = p.Q874= on NM_002238.4) | Silent (SNP) | VAF 4/44 reads (9%) | catalogued as COSV55082439; called by muse, mutect2
- KCNQ5 | c.2376G>A p.Q792= | Silent (SNP) | VAF 4/76 reads (5%) | catalogued as COSV59660716; called by muse, mutect2
- KRT1 | c.1308C>T p.A436= | Silent (SNP) | VAF 4/62 reads (6%) | catalogued as COSV52866920; called by muse, mutect2
- KRTAP3-2 | c.156C>T p.P52= | Silent (SNP) | VAF 5/72 reads (7%) | catalogued as rs774101098, COSV66957091; called by muse, mutect2
- LPA | c.3726G>A p.L1242= | Silent (SNP) | VAF 5/52 reads (10%) | catalogued as COSV60302341; called by muse, mutect2
- MACROH2A2 | c.66C>T p.I22= | Silent (SNP) | VAF 8/76 reads (11%) | catalogued as COSV64712891; called by muse, mutect2
- MCHR2 | c.939C>T p.F313= | Silent (SNP) | VAF 9/141 reads (6%) | catalogued as COSV56002663; called by muse, mutect2
- MLIP | c.94C>T p.L32= | Silent (SNP) | VAF 10/147 reads (7%) | catalogued as COSV51430222; called by muse, mutect2
- MUC16 | c.19377C>T p.T6459= | Silent (SNP) | VAF 18/254 reads (7%) | catalogued as rs556583250, COSV67467622; called by muse, mutect2
- MYD88 | c.802C>T p.L268= | Silent (SNP) | VAF 7/127 reads (6%) | catalogued as COSV57174384; called by muse, mutect2
- NLRP4 | c.546C>T p.F182= | Silent (SNP) | VAF 10/144 reads (7%) | catalogued as COSV100015830, COSV56714148; called by muse, mutect2
- NLRP5 | c.2172C>T p.S724= | Silent (SNP) | VAF 11/206 reads (5%) | catalogued as rs931392661, COSV66764667; called by muse, mutect2
- OR10H4 | c.87C>T p.F29= | Silent (SNP) | VAF 9/218 reads (4%) | catalogued as COSV59061544; called by muse, mutect2
- OR10K2 | c.855C>T p.F285= | Silent (SNP) | VAF 6/78 reads (8%) | catalogued as COSV59221253; called by muse, mutect2
- OR10R2 | c.117C>T p.S39= | Silent (SNP) | VAF 6/112 reads (5%) | catalogued as COSV63768840; called by muse, mutect2
- OR1L8 | c.279C>T p.I93= | Silent (SNP) | VAF 8/94 reads (9%) | catalogued as COSV59186443, COSV59187158; called by muse, mutect2
- OR2Z1 | c.486C>T p.I162= | Silent (SNP) | VAF 12/152 reads (8%) | catalogued as COSV60691770; called by muse, mutect2
- OR5A1 | c.468C>T p.F156= | Silent (SNP) | VAF 12/306 reads (4%) | catalogued as COSV57376771; called by muse, mutect2
- OR9A4 | c.48C>T p.F16= | Silent (SNP) | VAF 9/191 reads (5%) | catalogued as COSV71885476; called by muse, mutect2
- OR9A4 | c.747G>A p.V249= | Silent (SNP) | VAF 8/75 reads (11%) | catalogued as COSV71885477; called by muse, mutect2, varscan2
- OSMR | c.51C>T p.S17= | Silent (SNP) | VAF 6/96 reads (6%) | catalogued as rs1202277508, COSV57085458; called by muse, mutect2
- P2RY13 | c.162T>G p.V54= | Silent (SNP) | VAF 6/142 reads (4%) | catalogued as COSV56379618; called by muse, mutect2
- PKHD1 | c.6573C>T p.S2191= | Silent (SNP) | VAF 8/242 reads (3%) | catalogued as COSV61869750; called by muse, mutect2
- PRAMEF2 | c.658C>T p.L220= | Silent (SNP) | VAF 6/144 reads (4%) | catalogued as COSV53575619; called by muse, mutect2
- PROKR2 | c.915C>T p.F305= | Silent (SNP) | VAF 5/66 reads (8%) | catalogued as rs1351399715, COSV54085406; called by muse, mutect2
- RBM41 | c.708C>T p.L236= | Silent (SNP) | VAF 4/32 reads (13%) | catalogued as COSV52562159; called by muse, mutect2
- RCL1 | c.237C>T p.L79= | Silent (SNP) | VAF 12/241 reads (5%) | catalogued as rs1381210742, COSV67755723; called by muse, mutect2
- RHBDL1 | c.696G>A p.K232= (on ENST00000219551 / NM_001318733.2; = p.K167= on NM_001278720.2) | Silent (SNP) | VAF 5/50 reads (10%) | catalogued as rs372614912; called by mutect2, varscan2
- RIMKLA | c.535C>T p.L179= | Silent (SNP) | VAF 15/143 reads (10%) | catalogued as COSV68909784; called by muse, mutect2, varscan2
- RPAP1 | c.3705C>G p.P1235= | Silent (SNP) | VAF 3/28 reads (11%) | catalogued as COSV58539164; called by muse, mutect2
- SLC6A16 | c.1590C>T p.F530= | Silent (SNP) | VAF 12/252 reads (5%) | catalogued as COSV60028111; called by muse, mutect2
- SPATA31D1 | c.477G>A p.L159= | Silent (SNP) | VAF 6/60 reads (10%) | catalogued as COSV61196097; called by muse, mutect2
- SYNE1 | c.42C>T p.I14= | Silent (SNP) | VAF 10/174 reads (6%) | catalogued as rs1329904940, COSV54976444; called by muse, mutect2
- TAS2R38 | c.117G>A p.V39= | Silent (SNP) | VAF 6/90 reads (7%) | catalogued as COSV71885236; called by muse, mutect2
- TNXB | c.8176C>T p.L2726= (on ENST00000647633; = p.L2479= on NM_019105.8 and 1 other RefSeq transcript) | Silent (SNP) | VAF 18/484 reads (4%) | catalogued as COSV64479405; called by muse, mutect2
- TUBAL3 | c.822C>T p.F274= | Silent (SNP) | VAF 11/210 reads (5%) | catalogued as COSV66814262; called by muse, mutect2
- TUSC3 | c.663C>T p.N221= | Silent (SNP) | VAF 7/140 reads (5%) | catalogued as COSV65881517; called by muse, mutect2
- EPPIN | c.92-15C>A | Intron (SNP) | VAF 7/82 reads (9%) | catalogued as COSV100323078; called by muse, mutect2
- PIP5K1B | c.69+1455C>T | Intron (SNP) | VAF 14/315 reads (4%) | catalogued as COSV99597768; called by muse, mutect2
- STAU1 | c.610-11C>T | Intron (SNP) | VAF 7/92 reads (8%) | catalogued as COSV100574215; called by muse, mutect2
